Surgical pathology report (de-identified scan), TCGA case TCGA-05-4422, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4422-01A (Primary Tumor).

Main diagnosis/diagnoses:

Peripheral bronchopulmonary, histologically predominantly well differentiated mixed adenocarcinoma of the left lower lobe of the lung. TNM classification on the basis of this material pT2 pN0 R0, stage IB. C34.3 M8255/3.

Comment/supplementary remark:

The classification of the adenocarcinoma of the lung is based on the result of the immunohistochemical analysis obtained on the previous biopsy material. The tumor has a compact, low stromal structure, of predominantly tubulopapillary differentiation and shows a small bronchioloalveolar component at the margin. It extends to below the pleura, which it has not however infiltrated on the basis of the sample examined. In a central direction the carcinoma has invaded a peripheral bronchus, this being markedly distended and largely obstructed by a tumor plug.

Source: NCI Genomic Data Commons file 4e6a7f30-75df-44a5-9bc7-913b65f374a8 (TCGA-05-4422.B51045CA-F7AE-459F-90B7-631683D84E0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).